Gene-level copy-number profile of tumor specimen TCGA-71-8520-01A from TCGA case TCGA-71-8520, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.0 years (21,921 days).
Specimen TCGA-71-8520-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.30a8fcf2-85f3-43ae-8d73-3b8489cffbe2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-71-8520-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate.
https://portal.gdc.cancer.gov/files/437de6c6-52f9-4dce-a9fa-f38de4cecf98

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 5,671; copy number 2: 21,781; copy number 3: 16,793; copy number 4: 14,351; copy number 6: 1,188.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,824,213, 11 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,188 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,112,949–35,193,145, 23 genes, copy number 6: RNA5SP42, C1orf94, AC115286.1, AC099565.1, MIR552, SMIM12, GJB5, GJB4, AL121988.1, GJB3, GJA4, AL122010.1, DLGAP3, AC114490.3, AC114490.1, AC114490.2, TMEM35B, ZMYM6, ZMYM1, RPL12P45, EFCAB14P1, AL590434.1, SFPQ.
- chr1:44,635,238–47,704,029, 113 genes, copy number 6 (broad region; genes not listed).
- chr1:75,521,562–75,724,049, 4 genes, copy number 6 (within-gene range 2–6): AC093156.1, RNU6-503P, AL096829.1, AL137803.1.
- chr7:70,972–57,245,931, 1,048 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,661. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
